FM case AD16793 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/65c81467-4d0d-42f8-8e5e-dbeec0d3df40

Female, 59.2 years: Carcinosarcoma, NOS (ICD-O-3 8980/3) of the ovary; primary biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
